Somatic mutation profile of tumor specimen TCGA-KO-8403-01A (aliquot TCGA-KO-8403-01A-11D-2310-10) from TCGA case TCGA-KO-8403, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 49.7 years (18,171 days).
Specimen TCGA-KO-8403-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d8d848d-2e31-44d6-9f91-0d95afb4ab8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8403-11A (Solid Tissue Normal), aliquot TCGA-KO-8403-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/193e4bfd-3bd5-427f-ad11-959d981a2815

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 11/25 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs55832599, CM120851, COSV52678166, COSV52736883, COSV52827473; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 5/66 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ATG7 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as rs1005891334, COSV100608096; called by muse, mutect2, varscan2
- CHD4 | c.2327A>G p.N776S (on ENST00000357008 / NM_001363606.2; = p.N789S on NM_001273.5) | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58908170; called by muse, mutect2, varscan2
- CSMD2 | c.7462G>A p.G2488R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374084658; called by muse, mutect2, varscan2
- ELOA2 | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as COSV99798359; called by muse, mutect2, varscan2
- FAM13A | c.2300C>A p.P767H | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99984790; called by muse, mutect2
- GPATCH4 | c.629del p.K210Rfs*73 | Frame Shift Del (DEL) | VAF 6/29 reads (21%) | catalogued as rs754640631; called by mutect2, varscan2
- PRDM2 | c.743C>T p.P248L | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.021); catalogued as COSV99342856; called by muse, mutect2, varscan2
- RTCB | c.497+1G>T p.X166_splice | Splice Site (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99322449; called by muse, mutect2, varscan2
- SIRT3 | c.1192_1195del p.D398Nfs*10 | Frame Shift Del (DEL) | VAF 37/96 reads (39%) | catalogued as rs769058001; called by mutect2, pindel, varscan2
- SIX4 | c.1222A>T p.T408S | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99382557; called by muse, mutect2, varscan2
- ZNF419 | c.645A>C p.K215N | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99692680; called by muse, mutect2, varscan2
- ZNF497 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.112); catalogued as rs771227844, COSV54054174; called by muse, mutect2, varscan2
- ZNF846 | c.462C>G p.N154K | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV101194402; called by muse, mutect2, varscan2
- DSCAML1 | c.4893C>T p.Y1631= (on ENST00000321322; = p.Y1571= on NM_020693.4) | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs750769533, COSV58381896; called by muse, mutect2, varscan2
- ISCA1 | c.39G>T p.V13= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100276543; called by muse, mutect2, varscan2
- MUC2 | c.96C>T p.H32= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs1177888182; called by muse, mutect2, varscan2
- YDJC | c.849G>A p.R283= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99489023; called by muse, mutect2, varscan2
